CCDI case PBBSEY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/dc4442c6-1848-41b7-9bfe-ccd7b0340660

Demographics
Sex at birth: female; Vital status: Dead.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,747 days).

Biospecimens (3 samples)
- Sample 0DFO14: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFO17: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFO1Q: Tissue type: Tumor; Specimen type: Solid Tissue.
